Somatic mutation profile of tumor specimen TARGET-20-PATKLS-09A (aliquot TARGET-20-PATKLS-09A-01D) from TARGET case TARGET-20-PATKLS, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.4 years (3,447 days).
Specimen TARGET-20-PATKLS-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0707a6c1-96ab-42ac-a5bb-cbe07d288a91.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATKLS-14A (Bone Marrow Normal), aliquot TARGET-20-PATKLS-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2ecda04-54b7-4375-a1e1-1e916086a059

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Splice Site 2, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 36/114 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.692); catalogued as rs121913528, COSV55499283, COSV55796966; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PHF6 | c.586-2A>G p.X196_splice (on ENST00000332070 / NM_032458.3; = p.X197_splice on NM_032335.3) | Splice Site (SNP) | VAF 52/116 reads (45%) | catalogued as COSV59699942; called by muse, mutect2, varscan2
- RUNX1 | c.427+1G>A p.X143_splice (on ENST00000344691 / NM_001001890.3; = p.X170_splice on NM_001754.5) | Splice Site (SNP) | VAF 49/98 reads (50%) | catalogued as CS1312704, COSV55869348, COSV55878661; called by muse, mutect2, varscan2
